Somatic mutation profile of cancer-model specimen HCM-CSHL-0736-C18-85N (3D Organoid, passage 4; aliquot HCM-CSHL-0736-C18-85N-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0736-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 44.1 years (16,114 days).
Specimen HCM-CSHL-0736-C18-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a01dc7c0-af89-43ca-a8b5-2ecc4c0d9d88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0736-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0736-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8abd2a7-386c-4a83-84b7-0d1a3f5cfdf2

The open-access MAF lists 138 somatic variants for this specimen: 95 protein-altering or splice-affecting, 36 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 36, Nonsense Mutation 8, Frame Shift Ins 7, Intron 7, Frame Shift Del 4, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 163/163 reads (100%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 239/467 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.589G>C p.V197L | Missense Mutation (SNP) | VAF 232/232 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs786204041, CM070297, COSV52711079, COSV52927251, COSV53163944; ClinVar: uncertain significance; called by muse, varscan2
- ABCA7 | c.5176C>T p.R1726C | Missense Mutation (SNP) | VAF 210/463 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs754392161, COSV54030122; called by muse, mutect2, varscan2
- ACTL8 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 146/327 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs768803261, COSV64862417; called by muse, varscan2
- ADAMTS5 | c.1124C>A p.S375* | Nonsense Mutation (SNP) | VAF 187/390 reads (48%) | catalogued as COSV53179428; called by muse, mutect2, varscan2
- AGBL1 | c.3331G>A p.D1111N | Missense Mutation (SNP) | VAF 31/464 reads (7%) | PolyPhen benign (0); catalogued as COSV71424996; called by muse, mutect2
- ASAP2 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 225/445 reads (51%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.975); catalogued as rs919010572, COSV55634729, COSV55636496; called by muse, mutect2, varscan2
- CAPSL | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 220/452 reads (49%) | catalogued as rs575446116, COSV101274236, COSV68438376; called by muse, varscan2
- CCDC168 | c.13741C>T p.R4581* | Nonsense Mutation (SNP) | VAF 215/482 reads (45%) | catalogued as rs200024386; called by muse, mutect2, varscan2
- CDK16 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 616/1200 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.233); catalogued as rs763966261; called by muse, mutect2, varscan2
- CELSR1 | c.3400G>A p.V1134M | Missense Mutation (SNP) | VAF 392/817 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs370541822; called by muse, varscan2
- CUL9 | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 180/346 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs770578201; called by muse, varscan2
- DNAH5 | c.5131C>T p.R1711* | Nonsense Mutation (SNP) | VAF 147/325 reads (45%) | catalogued as rs760869074, COSV54240972; called by muse, varscan2
- EPHB6 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 233/530 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67418116; called by muse, mutect2, varscan2
- FAM184A | c.2168C>T p.T723M | Missense Mutation (SNP) | VAF 178/409 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs372303662, COSV58853616; called by muse, mutect2, varscan2
- FCRL4 | c.1322G>T p.C441F | Missense Mutation (SNP) | VAF 190/410 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1387326082, COSV54866026; called by muse, mutect2, varscan2
- FGF13 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 414/830 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as rs201229168, COSV59547071; called by muse, mutect2, varscan2
- GNA15 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 344/685 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs761338145; called by muse, mutect2, varscan2
- GNAS | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 389/1258 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs570213695, COSV58327309; called by muse, mutect2, varscan2
- GRM7 | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 198/444 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1114167301, COSV63138097; called by muse, varscan2
- HK3 | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 226/468 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs767374612, COSV52844040; called by muse, varscan2
- HNMT | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 125/396 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as rs755441595, COSV54508975; called by muse, mutect2, varscan2
- KCNH4 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 247/516 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as rs576758601, COSV99236821; called by muse, varscan2
- KIAA0100 | c.2959G>A p.V987M | Missense Mutation (SNP) | VAF 258/550 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1482910181; called by muse, mutect2, varscan2
- KIAA1109 | c.7924C>T p.R2642W | Missense Mutation (SNP) | VAF 196/453 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs770918038, COSV99167962; called by muse, mutect2, varscan2
- MAGEC1 | c.2739C>A p.D913E | Missense Mutation (SNP) | VAF 526/1040 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV99595087; called by muse, varscan2
- MAGI2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 192/426 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1470111212, COSV62670057; called by muse, mutect2, varscan2
- NF1 | c.4437C>A p.F1479L (on ENST00000358273 / NM_001042492.3; = p.F1458L on NM_000267.3) | Missense Mutation (SNP) | VAF 137/290 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV100646532; called by muse, mutect2, varscan2
- PCDHGA9 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 304/617 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.298); catalogued as COSV53917968; called by muse, varscan2
- PCDHGA9 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 166/386 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.035); catalogued as COSV53897324; called by muse, varscan2
- PCOLCE2 | c.813dup p.L272Tfs*31 | Frame Shift Ins (INS) | VAF 190/441 reads (43%) | catalogued as rs752255624; called by mutect2, varscan2
- PORCN | c.1094G>A p.R365Q (on ENST00000326194 / NM_203475.3; = p.R354Q on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 564/1177 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM093035, COSV58226234; called by muse, mutect2, varscan2
- RASSF2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 262/761 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.714); catalogued as rs755156690, COSV65081598; called by mutect2, varscan2
- RHOH | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 246/503 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs750167394; called by muse, varscan2
- ROBO1 | c.4003G>A p.D1335N | Missense Mutation (SNP) | VAF 250/560 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs949724928; called by muse, mutect2, varscan2
- RPGRIP1 | c.3749-1G>C p.X1250_splice | Splice Site (SNP) | VAF 228/429 reads (53%) | catalogued as rs769076483, CS1310173; called by muse, mutect2, varscan2
- RUFY4 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 540/819 reads (66%) | catalogued as rs755454736, COSV60247439; called by muse, mutect2, varscan2
- SGSM2 | c.2150C>T p.S717L (on ENST00000426855 / NM_001098509.2; = p.S762L on NM_014853.3) | Missense Mutation (SNP) | VAF 281/283 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs766584818; called by muse, varscan2
- SLC22A3 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 158/356 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1043162832, COSV51709731; called by muse, varscan2
- SLC8A2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 324/703 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs746692355, COSV52639635; called by muse, varscan2
- SMIM9 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 279/632 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs199975971; called by muse, varscan2
- TEX13C | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 306/1128 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.088); catalogued as rs1217207081, COSV50143683; called by muse, mutect2, varscan2
- TMEM132D | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 280/533 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.753); catalogued as rs184779750, COSV104436973, COSV70597269; called by muse, mutect2, varscan2
- TRIM56 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 334/705 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1161129455; called by muse, mutect2, varscan2
- USH2A | c.11574G>A p.M3858I | Missense Mutation (SNP) | VAF 213/373 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs767933081; called by muse, mutect2, varscan2
- ZNF467 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 450/981 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1282223335, COSV57373520; called by muse, varscan2
- ABCG2 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 225/497 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- AIG1 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 196/423 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ANXA7 | c.1370dup p.M457Ifs*17 (on ENST00000372919 / NM_001320880.2; = p.M435Ifs*17 on NM_001156.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 111/328 reads (34%) | called by mutect2, pindel, varscan2
- ATG2B | c.5412G>T p.Q1804H | Missense Mutation (SNP) | VAF 168/385 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP13A3 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 191/402 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BNC1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 177/343 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- CD276 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 355/679 reads (52%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP350 | c.2025dup p.H676Sfs*21 | Frame Shift Ins (INS) | VAF 154/422 reads (36%) | called by pindel, varscan2
- DNAJC14 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 311/705 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN1 | c.3343G>T p.D1115Y | Missense Mutation (SNP) | VAF 112/257 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FLRT3 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 215/630 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDA | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 310/359 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1075A>G p.M359V | Missense Mutation (SNP) | VAF 322/2445 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, varscan2
- GP2 | c.786C>G p.S262R (on ENST00000381362 / NM_001007240.3; = p.S259R on NM_001502.4) | Missense Mutation (SNP) | VAF 23/715 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2
- GRPR | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 668/1393 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, varscan2
- HNF4G | c.635T>A p.I212N (on ENST00000354370 / NM_001330561.2; = p.I259N on NM_004133.5) | Missense Mutation (SNP) | VAF 273/456 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HUWE1 | c.12736G>T p.E4246* | Nonsense Mutation (SNP) | VAF 50/1576 reads (3%) | called by muse, mutect2
- IL1RAPL1 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 280/1176 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- KIAA1109 | c.12143G>A p.R4048Q | Missense Mutation (SNP) | VAF 141/291 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIF5B | c.2496C>G p.I832M | Missense Mutation (SNP) | VAF 162/332 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KMT2D | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 346/868 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- MED26 | c.52G>C p.A18P | Missense Mutation (SNP) | VAF 396/823 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MUC16 | c.1042del p.S348Pfs*34 | Frame Shift Del (DEL) | VAF 272/752 reads (36%) | called by pindel, varscan2
- MYO16 | c.4129G>A p.A1377T | Missense Mutation (SNP) | VAF 340/680 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFATC2 | c.1506dup p.E504Gfs*19 | Frame Shift Ins (INS) | VAF 189/620 reads (30%) | called by mutect2, pindel, varscan2
- NKX2-6 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 98/600 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, varscan2
- NXF3 | c.1478T>G p.F493C | Missense Mutation (SNP) | VAF 207/857 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR4P4 | c.839T>C p.F280S | Missense Mutation (SNP) | VAF 283/558 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- OTUB2 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 57/992 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2
- PANK3 | c.257_258dup p.F87Gfs*58 | Frame Shift Ins (INS) | VAF 243/680 reads (36%) | called by pindel, varscan2
- PLCL2 | c.556A>C p.I186L (on ENST00000615277 / NM_001144382.2; = p.I60L on NM_015184.5) | Missense Mutation (SNP) | VAF 250/526 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PPM1J | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 298/626 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); called by muse, varscan2
- RASSF6 | c.200T>C p.F67S (on ENST00000342081 / NM_201431.2; = p.F35S on NM_177532.5) | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- REEP3 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 141/312 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SCN9A | c.1484del p.G495Efs*70 | Frame Shift Del (DEL) | VAF 280/995 reads (28%) | called by mutect2, pindel, varscan2
- SHC2 | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 249/516 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- SHC4 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 326/634 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SMG7 | c.408del p.S137Afs*3 | Frame Shift Del (DEL) | VAF 266/643 reads (41%) | called by mutect2, pindel, varscan2
- SPSB3 | c.279_291del p.D93Efs*14 | Frame Shift Del (DEL) | VAF 198/509 reads (39%) | called by mutect2, pindel, varscan2
- TCEAL9 | c.19dup p.M7Nfs*8 | Frame Shift Ins (INS) | VAF 290/634 reads (46%) | called by mutect2, varscan2
- TCF4 | c.326A>C p.Y109S | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2
- TG | c.6220A>G p.S2074G | Missense Mutation (SNP) | VAF 81/583 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM24 | c.3025dup p.R1009Kfs*10 (on ENST00000343526 / NM_015905.3; = p.R975Kfs*10 on NM_003852.4) | Frame Shift Ins (INS) | VAF 112/347 reads (32%) | called by mutect2, pindel, varscan2
- UBXN6 | c.-2_19del | Translation Start Site (DEL) | VAF 98/266 reads (37%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.29C>A p.S10* | Nonsense Mutation (SNP) | VAF 44/446 reads (10%) | called by muse, mutect2
- ZNF283 | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 210/446 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.264); called by muse, varscan2
- ZNF292 | c.2833C>G p.Q945E | Missense Mutation (SNP) | VAF 224/438 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF688 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 422/891 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- ASTN1 | c.627C>T p.I209= | Silent (SNP) | VAF 328/688 reads (48%) | catalogued as rs757444447, COSV56090618; called by muse, varscan2
- CASR | c.1455C>T p.C485= (on ENST00000490131; = p.C562= on NM_000388.4) | Silent (SNP) | VAF 161/342 reads (47%) | catalogued as rs193922428; ClinVar: likely benign; called by muse, varscan2
- CERK | c.501C>A p.I167= | Silent (SNP) | VAF 203/404 reads (50%) | catalogued as rs765563017; called by muse, mutect2, varscan2
- CPLX1 | c.234C>T p.R78= | Silent (SNP) | VAF 102/648 reads (16%) | catalogued as COSV100408388; called by muse, varscan2
- CRISPLD2 | c.729A>G p.K243= | Silent (SNP) | VAF 218/458 reads (48%) | called by muse, varscan2
- DPP6 | c.2253G>A p.A751= (on ENST00000377770 / NM_001364500.2; = p.A689= on NM_001936.5) | Silent (SNP) | VAF 155/346 reads (45%) | catalogued as rs748957885, COSV59599208; called by muse, mutect2, varscan2
- DYNC2I1 | c.2836C>T p.L946= | Silent (SNP) | VAF 288/656 reads (44%) | catalogued as rs1214089806; called by muse, mutect2, varscan2
- EFS | c.1248G>A p.P416= | Silent (SNP) | VAF 285/563 reads (51%) | catalogued as rs146654160; called by muse, varscan2
- FOXJ1 | c.288G>A p.T96= | Silent (SNP) | VAF 523/1032 reads (51%) | catalogued as COSV99486442; called by muse, mutect2, varscan2
- GKN2 | c.480C>T p.V160= | Silent (SNP) | VAF 291/291 reads (100%) | catalogued as rs556298042, COSV61031562; called by muse, mutect2, varscan2
- GOLGA6C | c.690C>T p.D230= | Silent (SNP) | VAF 276/1184 reads (23%) | catalogued as rs542509525; called by muse, varscan2
- GORASP2 | c.1176C>T p.N392= | Silent (SNP) | VAF 86/1344 reads (6%) | catalogued as rs756232157; called by muse, mutect2
- KCNH1 | c.1359G>A p.S453= (on ENST00000271751 / NM_172362.3; = p.S426= on NM_002238.4) | Silent (SNP) | VAF 216/444 reads (49%) | catalogued as rs764070927, COSV55081074, COSV55104814; ClinVar: likely benign; called by muse, varscan2
- KCNN1 | c.48C>T p.S16= | Silent (SNP) | VAF 420/837 reads (50%) | catalogued as rs540542401, COSV55838263; called by muse, varscan2
- KIF26B | c.1527C>T p.F509= | Silent (SNP) | VAF 308/670 reads (46%) | catalogued as COSV63643967, COSV63647751; called by muse, mutect2, varscan2
- MAP2K7 | c.1173G>A p.A391= | Silent (SNP) | VAF 292/651 reads (45%) | catalogued as rs766586869, COSV101208951; called by muse, mutect2, varscan2
- MAST2 | c.1041G>A p.V347= | Silent (SNP) | VAF 280/585 reads (48%) | called by muse, mutect2, varscan2
- MYO16 | c.4155C>T p.R1385= | Silent (SNP) | VAF 342/674 reads (51%) | called by muse, varscan2
- MYO7B | c.3537T>C p.R1179= | Silent (SNP) | VAF 35/1183 reads (3%) | called by muse, mutect2
- NPY2R | c.930C>T p.F310= | Silent (SNP) | VAF 259/503 reads (51%) | called by muse, mutect2, varscan2
- PIWIL2 | c.2901C>T p.C967= | Silent (SNP) | VAF 177/461 reads (38%) | catalogued as rs138997865; called by muse, mutect2, varscan2
- PPP4R3C | c.732C>T p.N244= | Silent (SNP) | VAF 392/835 reads (47%) | catalogued as rs781660355, COSV69081005; called by muse, mutect2, varscan2
- PRMT8 | c.1014C>T p.T338= | Silent (SNP) | VAF 254/553 reads (46%) | catalogued as rs367772639; called by muse, mutect2, varscan2
- SARS1 | c.354C>T p.D118= | Silent (SNP) | VAF 253/484 reads (52%) | catalogued as rs749824433; called by muse, mutect2, varscan2
- SCN7A | c.4387A>C p.R1463= | Silent (SNP) | VAF 230/763 reads (30%) | called by muse, mutect2, varscan2
- SERPINB11 | c.714C>T p.Y238= | Silent (SNP) | VAF 207/208 reads (100%) | catalogued as rs368222195; called by muse, varscan2
- SFMBT2 | c.1173G>A p.A391= | Silent (SNP) | VAF 206/438 reads (47%) | catalogued as rs143424241, COSV62812649; called by muse, varscan2
- SLC1A6 | c.612G>A p.T204= | Silent (SNP) | VAF 257/474 reads (54%) | catalogued as rs141513404; called by muse, mutect2, varscan2
- SMURF2 | c.558G>A p.E186= | Silent (SNP) | VAF 153/386 reads (40%) | called by muse, mutect2, varscan2
- THAP8 | c.318G>A p.P106= | Silent (SNP) | VAF 271/610 reads (44%) | catalogued as rs367994008; called by muse, mutect2, varscan2
- TMEM182 | c.540C>T p.Y180= | Silent (SNP) | VAF 228/724 reads (31%) | called by muse, mutect2, varscan2
- TSHR | c.1524G>A p.S508= | Silent (SNP) | VAF 262/559 reads (47%) | catalogued as rs148477562; called by muse, varscan2
- UBQLN1 | c.1044T>C p.S348= | Silent (SNP) | VAF 66/432 reads (15%) | called by muse, mutect2, varscan2
- XPNPEP1 | c.1587G>A p.G529= | Silent (SNP) | VAF 260/526 reads (49%) | catalogued as rs920869143; called by muse, mutect2, varscan2
- ZNF335 | c.3561C>T p.I1187= | Silent (SNP) | VAF 136/409 reads (33%) | catalogued as rs148934939; ClinVar: likely benign; called by muse, varscan2
- ZSWIM8 | c.2421C>T p.L807= | Silent (SNP) | VAF 230/510 reads (45%) | catalogued as COSV67133263; called by muse, mutect2, varscan2
- ARMH3 | c.414+65C>T | Intron (SNP) | VAF 292/610 reads (48%) | catalogued as rs1429481274, COSV100228998; called by muse, varscan2
- DIABLO | c.305-1269C>T | Intron (SNP) | VAF 58/608 reads (10%) | catalogued as rs761049707; called by muse, mutect2
- DYSF | c.458-449G>A | Intron (SNP) | VAF 188/420 reads (45%) | called by muse, varscan2
- DYSF | c.458-448G>T | Intron (SNP) | VAF 186/420 reads (44%) | called by muse, varscan2
- PTN | c.452-8161G>T | Intron (SNP) | VAF 209/439 reads (48%) | catalogued as COSV61963975; called by muse, mutect2, varscan2
- RAB28 | c.574-1252C>G | Intron (SNP) | VAF 34/466 reads (7%) | called by muse, mutect2
- ZNF138 | c.209-500A>G | Intron (SNP) | VAF 161/327 reads (49%) | called by muse, mutect2, varscan2
